Somatic mutation profile of tumor specimen ALCH-B021-TTP1-A (aliquot ALCH-B021-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B021, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.7 years (25,826 days).
Specimen ALCH-B021-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad7f71c9-2a5b-4e52-ae9c-2d059963db38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B021-NB1-A (Blood Derived Normal), aliquot ALCH-B021-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bc7f1d1-e061-4cdf-bd3a-b7e14fd0e29d

The open-access MAF lists 342 somatic variants for this specimen: 226 protein-altering or splice-affecting, 75 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 196, Silent 75, Nonsense Mutation 18, RNA 15, Intron 12, Frame Shift Del 6, 3'UTR 5, 5'UTR 5, 3'Flank 3, Splice Site 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HBB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 48/283 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs33930702, CM920317, CM930364, CM973762; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 71/123 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50266507; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 181/330 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.546); catalogued as rs939451589, COSV100229480, COSV55297546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.2260C>G p.R754G | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV52225146; called by muse, mutect2, varscan2
- ABCD2 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100429208; called by muse, mutect2
- AC013489.1 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1481866048; called by muse, mutect2, varscan2
- ACSS3 | c.1772A>T p.D591V | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268865994, COSV54102183; called by muse, mutect2
- ADAMTS18 | c.2060A>T p.K687M | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV51402235; called by muse, mutect2, varscan2
- AMER3 | c.2017C>A p.L673M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV58467866, COSV58468360; called by muse, mutect2, varscan2
- ANKRD30A | c.3885G>T p.M1295I (on ENST00000611781; = p.M1239I on NM_052997.2) | Missense Mutation (SNP) | VAF 174/467 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64619968; called by muse, mutect2, varscan2
- AOC3 | c.1966C>G p.P656A | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1372951511; called by muse, mutect2, varscan2
- CDH9 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 27/702 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151493; called by muse, mutect2
- CDNF | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 31/312 reads (10%) | catalogued as COSV65806086; called by muse, varscan2
- CNGA4 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as rs764594438; called by muse, mutect2
- CNKSR2 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.137); catalogued as COSV99669541; called by muse, mutect2
- CNOT1 | c.6308T>C p.L2103S | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326406314; called by muse, mutect2, varscan2
- DCHS1 | c.6586G>T p.D2196Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1215321536; called by muse, mutect2, varscan2
- DIO3 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236381409, COSV63773343; called by muse, mutect2, varscan2
- DLC1 | c.1739G>A p.G580D (on ENST00000276297 / NM_001348081.2; = p.G143D on NM_006094.5) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1224102610, COSV52304859; called by muse, mutect2, varscan2
- DLC1 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV52323392; called by muse, mutect2
- DNAJC21 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV57760486; called by muse, mutect2
- EPHB1 | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 296/356 reads (83%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV67660520; called by muse, mutect2, varscan2
- EYS | c.3743C>T p.P1248L | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs993603647; called by muse, mutect2, varscan2
- FBP2 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100942191; called by muse, mutect2, varscan2
- FREM1 | c.5461G>C p.D1821H | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV66521419; called by muse, mutect2
- GABRG1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs780057500; called by muse, mutect2
- GPSM1 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as rs370718104; called by muse, mutect2
- GTF3C2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 244/486 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV53127722; called by muse, mutect2, varscan2
- HDAC4 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV61873301; called by muse, mutect2, varscan2
- HS3ST5 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as rs529073825, COSV100450816; called by muse, mutect2, varscan2
- HSD17B4 | c.1930G>T p.G644C (on ENST00000414835 / NM_001199291.3; = p.G619C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/445 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV56338303; called by muse, mutect2, varscan2
- HYDIN | c.544A>C p.T182P | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55486665; called by muse, mutect2, varscan2
- IFI44L | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 157/305 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs759991643; called by muse, mutect2, varscan2
- ISLR | c.980G>T p.C327F | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51434087; called by muse, mutect2, varscan2
- KCNJ5 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.65); catalogued as rs748056169; called by muse, mutect2, varscan2
- KRCC1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 122/296 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs778179732; called by muse, mutect2, varscan2
- LAMC1 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99279074; called by muse, mutect2, varscan2
- MAB21L2 | c.998C>A p.S333* | Nonsense Mutation (SNP) | VAF 29/46 reads (63%) | catalogued as COSV58262791; called by muse, mutect2, varscan2
- MAGEB6 | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201604663, COSV66872010, COSV66872099; called by muse, mutect2, varscan2
- MAP3K7 | c.1702G>C p.V568L (on ENST00000369329 / NM_145331.3; = p.V541L on NM_003188.4) | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1457817469; called by muse, mutect2, varscan2
- MRPL17 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as rs753227340; called by muse, mutect2, varscan2
- MYBPC2 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs768971834; called by muse, mutect2, varscan2
- NALCN | c.1010del p.G337Dfs*26 | Frame Shift Del (DEL) | VAF 169/388 reads (44%) | catalogued as COSV51932915; called by mutect2, pindel, varscan2
- NCAM2 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 209/428 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.715); catalogued as COSV53054274; called by muse, mutect2, varscan2
- NDST4 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 109/205 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV52116462; called by muse, mutect2, varscan2
- NELL2 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 38/435 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.379); catalogued as rs372651570; called by muse, mutect2
- NOTCH2 | c.852C>A p.C284* | Nonsense Mutation (SNP) | VAF 241/380 reads (63%) | catalogued as COSV56704946; called by muse, mutect2, varscan2
- NOTCH4 | c.1145C>A p.P382Q | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.069); catalogued as rs752469207; called by muse, mutect2, varscan2
- NRROS | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs778392129, COSV60744513, COSV60747684; called by muse, mutect2
- OR2L2 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs774346957, COSV63558123; called by muse, mutect2
- OR5D18 | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 164/317 reads (52%) | catalogued as COSV99082001; called by muse, mutect2, varscan2
- OR5D18 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 165/323 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs867205449, COSV61738934; called by muse, mutect2, varscan2
- OR9G4 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100265005; called by muse, mutect2, varscan2
- PCDH15 | c.5317C>A p.P1773T | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100226171; called by muse, mutect2
- PCDHA13 | c.1142C>A p.S381* | Nonsense Mutation (SNP) | VAF 51/176 reads (29%) | catalogued as COSV99165051; called by muse, mutect2, varscan2
- PIGR | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 174/560 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV62904303; called by muse, mutect2, varscan2
- PRKAR2B | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV55924987; called by muse, mutect2, varscan2
- PTPRK | c.3139G>T p.G1047C (on ENST00000368215 / NM_001291984.2; = p.G1048C on NM_002844.4) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100951425, COSV63898022; called by muse, mutect2, varscan2
- RFX6 | c.1322C>A p.T441N | Missense Mutation (SNP) | VAF 59/475 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60583851; called by muse, mutect2, varscan2
- RPS6KA6 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV99425439; called by muse, mutect2
- RUNX1T1 | c.1423G>T p.A475S (on ENST00000265814 / NM_001198628.1; = p.A448S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56139494; called by muse, mutect2
- SFMBT2 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 138/411 reads (34%) | catalogued as COSV62807137; called by muse, mutect2, varscan2
- SIGLEC1 | c.2174C>A p.A725D | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV52474420; called by muse, mutect2, varscan2
- SLITRK4 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 159/215 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV100567595; called by muse, mutect2, varscan2
- SLITRK5 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs756966467, COSV61527121; called by muse, mutect2, varscan2
- SNRPC | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 88/295 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1333942094; called by muse, mutect2, varscan2
- STARD13 | c.1127C>T p.P376L (on ENST00000336934 / NM_001243476.3; = p.P258L on NM_052851.3) | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771360121; called by muse, mutect2, varscan2
- TENM2 | c.4543G>T p.G1515W (on ENST00000518659 / NM_001122679.2; = p.G1276W on NM_001080428.3) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69136542; called by muse, mutect2, varscan2
- THOP1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1055507788; called by muse, mutect2
- TOPBP1 | c.4550A>G p.K1517R | Missense Mutation (SNP) | VAF 74/810 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53439744, COSV99606087; called by muse, mutect2
- UFL1 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99054272; called by muse, mutect2, varscan2
- USP17L7 | c.1424T>A p.M475K | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs767173107; called by muse, mutect2, varscan2
- VCAM1 | c.2068A>C p.N690H | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54118565; called by muse, mutect2, varscan2
- WDFY4 | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.232); catalogued as COSV57422834; called by muse, mutect2
- ZACN | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.815); catalogued as rs748846097; called by muse, mutect2, varscan2
- ZFHX4 | c.6309C>A p.D2103E | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.255); catalogued as COSV50490459; called by muse, mutect2, varscan2
- ZIM2 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 16/331 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV99687096; called by muse, mutect2
- ZKSCAN7 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 81/114 reads (71%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.544); catalogued as COSV56272054; called by muse, mutect2, varscan2
- ZNF300 | c.1586C>G p.A529G | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV51050992; called by muse, mutect2, varscan2
- ZNF469 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1439032775, COSV101458870, COSV71258295; called by muse, mutect2, varscan2
- ZNF77 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs146262812; called by muse, mutect2
- ZNF835 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73379484; called by muse, mutect2, varscan2
- ACSM4 | c.989A>C p.K330T | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAM11 | c.2127C>A p.C709* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- ADCY5 | c.3437C>T p.T1146I | Missense Mutation (SNP) | VAF 36/598 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2
- AFF2 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGR2 | c.330+5G>A | Splice Region (SNP) | VAF 66/200 reads (33%) | called by muse, mutect2, varscan2
- AL358113.1 | c.3296G>T p.R1099L | Missense Mutation (SNP) | VAF 130/351 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- AMER3 | c.2016G>A p.M672I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.11421G>C p.E3807D | Missense Mutation (SNP) | VAF 159/277 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ARHGAP12 | c.2537G>T p.R846L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATPSCKMT | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 43/367 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- C2orf69 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- C5orf22 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 135/483 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CACNA1E | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CBLB | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 34/714 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CCDC74B | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- CCNB3 | c.3959G>T p.W1320L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.143); called by muse, mutect2
- CD69 | c.380_387+8delinsGGACATGGTAAGAATA p.X127_splice | Splice Site (ONP) | VAF 48/381 reads (13%) | called by mutect2*, pindel, varscan2*
- CFAP47 | c.2768T>C p.F923S | Missense Mutation (SNP) | VAF 97/150 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CLSTN2 | c.2416G>T p.V806L | Missense Mutation (SNP) | VAF 125/320 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CMPK2 | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CNTN6 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- COPZ2 | c.306C>A p.Y102* | Nonsense Mutation (SNP) | VAF 88/266 reads (33%) | called by muse, mutect2, varscan2
- CRB1 | c.1171+1G>T p.X391_splice | Splice Site (SNP) | VAF 364/748 reads (49%) | called by muse, mutect2, varscan2
- CUBN | c.8427T>G p.F2809L | Missense Mutation (SNP) | VAF 31/493 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CUBN | c.4223C>A p.P1408H | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYBB | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 55/349 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP4Z1 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DAGLB | c.494_499dup p.Y165_S166dup | In Frame Ins (INS) | VAF 85/320 reads (27%) | called by mutect2, varscan2
- DENND2B | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMD | c.6219G>T p.K2073N | Missense Mutation (SNP) | VAF 143/195 reads (73%) | SIFT tolerated (0.35); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DNAH11 | c.10777A>T p.K3593* | Nonsense Mutation (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- DOCK4 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2
- DPPA4 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- DPY19L2 | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- DYNC1I1 | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DYRK1B | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2S3B | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- EPHA6 | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- F5 | c.2461A>T p.N821Y | Missense Mutation (SNP) | VAF 166/558 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- F5 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 214/685 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- FAM135A | c.1190A>T p.E397V (on ENST00000370479 / NM_001351599.1; = p.E380V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FGF12 | c.650G>T p.G217V (on ENST00000454309 / NM_021032.5; = p.G155V on NM_004113.6) | Missense Mutation (SNP) | VAF 39/839 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- FITM2 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.493); called by muse, mutect2
- FMN2 | c.2306G>A p.C769Y | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GMCL1 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- GRIA4 | c.1609T>A p.F537I | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- HAMP | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HCN4 | c.3389G>A p.G1130E | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPUL1 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- HPSE2 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 91/294 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HRH1 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ICA1L | c.721A>T p.M241L | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- IMPG2 | c.1070A>T p.Y357F | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.162); called by muse, mutect2
- JADE2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KCNJ3 | c.1425A>T p.Q475H | Missense Mutation (SNP) | VAF 124/278 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KDR | c.2141T>C p.V714A | Missense Mutation (SNP) | VAF 216/365 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.16); called by muse, varscan2
- KIF20B | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2
- KIF2A | c.495del p.K165Nfs*36 | Frame Shift Del (DEL) | VAF 44/204 reads (22%) | called by mutect2, pindel, varscan2
- KL | c.963C>G p.D321E | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.086); called by muse, mutect2
- KL | c.1829A>T p.Q610L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LAMA4 | c.2299C>T p.Q767* (on ENST00000230538 / NM_001105206.3; = p.Q760* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/417 reads (19%) | called by muse, mutect2, varscan2
- LDB2 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, varscan2
- LDHAL6A | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, mutect2
- LRFN3 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LRFN5 | c.252G>T p.R84S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEL2 | c.2662A>T p.K888* | Nonsense Mutation (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- MAN1A2 | c.1102A>T p.K368* | Nonsense Mutation (SNP) | VAF 97/176 reads (55%) | called by muse, mutect2, varscan2
- MAP3K11 | c.1880T>G p.V627G | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- METRN | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC17 | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NAP1L3 | c.844A>T p.K282* | Nonsense Mutation (SNP) | VAF 134/180 reads (74%) | called by muse, mutect2, varscan2
- NCAPG2 | c.1231A>G p.M411V | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NCOA1 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 32/409 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- NDRG2 | c.640A>C p.I214L (on ENST00000298687 / NM_001354570.1; = p.I200L on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/158 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NEXMIF | c.3758C>G p.S1253C | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NRAP | c.2144A>T p.E715V (on ENST00000359988 / NM_001322945.2; = p.E680V on NM_006175.4) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, varscan2
- NUDT6 | c.666T>G p.D222E | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NYNRIN | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10P1 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- OR11H2 | c.505C>T p.Q169* (on ENST00000556246; = p.Q180* on NM_001197287.1) | Nonsense Mutation (SNP) | VAF 36/618 reads (6%) | called by muse, mutect2
- OR2G6 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OR5K4 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 129/366 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- OR6C74 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2
- PCDHGA5 | c.2252A>T p.Q751L | Missense Mutation (SNP) | VAF 123/221 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PDE3A | c.2224T>G p.L742V | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDZD2 | c.3850C>A p.L1284I | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PEAK3 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKD1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- POLG2 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- POTEJ | c.2645T>C p.V882A | Missense Mutation (SNP) | VAF 176/724 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, varscan2
- PPP1R15B | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); called by muse, varscan2
- PRKCG | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PRKG2 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 109/192 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PTPRB | c.3349A>G p.I1117V | Missense Mutation (SNP) | VAF 145/418 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- RAB6C | c.623G>C p.C208S | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RECQL5 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNMT | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RYR1 | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 177/248 reads (71%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RYR2 | c.6758T>A p.L2253Q | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RYR3 | c.10106C>A p.A3369E (on ENST00000389232; = p.A3370E on NM_001036.6) | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- SCAF8 | c.1835T>A p.V612D | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SCN1A | c.2376G>T p.M792I (on ENST00000303395 / NM_001202435.3; = p.M781I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- SCN7A | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 108/536 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN8A | c.5375G>T p.W1792L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SENP7 | c.2224A>T p.T742S | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SIN3B | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SIPA1L3 | c.5240C>T p.A1747V | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SLC2A9 | c.408del p.R137Gfs*18 | Frame Shift Del (DEL) | VAF 159/356 reads (45%) | called by mutect2, pindel, varscan2
- SLC30A9 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SLC35G5 | c.716_717del p.F239Cfs*10 | Frame Shift Del (DEL) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- SORL1 | c.5072G>T p.S1691I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SORL1 | c.5073C>A p.S1691R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SPATA3 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- STEAP3 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK4 | c.1460del p.F487Sfs*80 | Frame Shift Del (DEL) | VAF 53/147 reads (36%) | called by mutect2, pindel, varscan2
- SVEP1 | c.656T>A p.F219Y | Missense Mutation (SNP) | VAF 245/554 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAS2R13 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TDRD15 | c.4052C>A p.A1351E | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TERB1 | c.2059A>T p.K687* | Nonsense Mutation (SNP) | VAF 22/303 reads (7%) | called by muse, mutect2
- TEX13A | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- THSD7B | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TIMP3 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 29/538 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TLL2 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRIM67 | c.1396C>A p.R466S | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.94788G>T p.L31596F (on ENST00000591111; = p.L24172F on NM_003319.4) | Missense Mutation (SNP) | VAF 22/496 reads (4%) | PolyPhen probably damaging (0.963); called by muse, mutect2
- UBL7 | c.663A>T p.P221= | Splice Region (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- UTP14C | c.585del p.K195Nfs*4 | Frame Shift Del (DEL) | VAF 161/336 reads (48%) | called by mutect2, pindel, varscan2
- WDFY4 | c.8086T>C p.F2696L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- XIRP2 | c.4798G>A p.E1600K (on ENST00000628543; = p.E1775K on NM_152381.6) | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ZC3H11A | c.1338G>T p.L446F | Missense Mutation (SNP) | VAF 46/753 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2
- ZDBF2 | c.4219G>A p.D1407N | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZDHHC2 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ZHX3 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF214 | c.1505A>G p.E502G | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ZNF285 | c.1429G>C p.V477L | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ZNF333 | c.1523G>T p.C508F | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF490 | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 98/161 reads (61%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ZNF507 | c.2364C>A p.C788* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- ZNF639 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 52/832 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF671 | c.105C>A p.H35Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF878 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- ZNF99 | c.2074C>G p.L692V | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- ADNP | c.2493A>G p.L831= | Silent (SNP) | VAF 86/453 reads (19%) | called by muse, mutect2, varscan2
- AGXT2 | c.27G>A p.L9= | Silent (SNP) | VAF 72/382 reads (19%) | catalogued as COSV51484572, COSV51487833; called by muse, mutect2, varscan2
- AL445989.1 | c.303A>T p.G101= | Silent (SNP) | VAF 220/431 reads (51%) | catalogued as rs1167871860; called by muse, mutect2, varscan2
- ANHX | c.135C>A p.A45= | Silent (SNP) | VAF 100/344 reads (29%) | called by muse, mutect2, varscan2
- ATF7IP2 | c.195C>T p.T65= | Silent (SNP) | VAF 16/396 reads (4%) | catalogued as rs1372544034; called by muse, mutect2
- B3GAT1 | c.477C>G p.R159= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV56998007; called by muse, mutect2, varscan2
- BMPER | c.99G>A p.G33= | Silent (SNP) | VAF 97/268 reads (36%) | called by muse, mutect2, varscan2
- CALCR | c.210A>G p.P70= | Silent (SNP) | VAF 76/234 reads (32%) | catalogued as rs761741558; called by muse, mutect2, varscan2
- CCDC168 | c.10468T>C p.L3490= | Silent (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- CENPE | c.5379C>A p.L1793= | Silent (SNP) | VAF 131/238 reads (55%) | called by muse, mutect2, varscan2
- CFAP47 | c.2766C>A p.G922= | Silent (SNP) | VAF 90/140 reads (64%) | called by muse, mutect2
- CLDN8 | c.198C>T p.I66= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV99729641; called by muse, mutect2, varscan2
- COL11A2 | c.111C>G p.A37= | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- COX18 | c.900A>G p.G300= | Silent (SNP) | VAF 90/173 reads (52%) | called by muse, mutect2, varscan2
- CREBRF | c.672G>A p.K224= | Silent (SNP) | VAF 133/223 reads (60%) | called by muse, mutect2, varscan2
- CSMD2 | c.2802C>G p.T934= | Silent (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- CYB5R4 | c.219A>T p.I73= | Silent (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.1197G>A p.G399= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV63584138; called by muse, mutect2, varscan2
- DOCK10 | c.2877G>A p.K959= | Silent (SNP) | VAF 216/329 reads (66%) | catalogued as rs1448315900; called by muse, mutect2, varscan2
- FAM83C | c.1242C>T p.L414= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as rs138016690; called by muse, mutect2
- FCSK | c.726C>T p.S242= | Silent (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- FLRT2 | c.1624C>T p.L542= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100421067, COSV58141203; called by muse, mutect2, varscan2
- GP9 | c.225C>A p.P75= | Silent (SNP) | VAF 137/392 reads (35%) | called by muse, mutect2, varscan2
- GRB10 | c.1011C>A p.A337= (on ENST00000398812; = p.A291= on NM_001001549.3) | Silent (SNP) | VAF 141/449 reads (31%) | catalogued as rs375141551; called by muse, mutect2, varscan2
- HUS1B | c.291G>T p.A97= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV57868022; called by muse, mutect2, varscan2
- HYDIN | c.13287T>C p.A4429= | Silent (SNP) | VAF 33/292 reads (11%) | called by muse, mutect2, varscan2
- ITGA10 | c.447C>T p.F149= | Silent (SNP) | VAF 161/340 reads (47%) | called by muse, mutect2, varscan2
- LGALS3BP | c.987C>T p.S329= | Silent (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- LRRC26 | c.723C>T p.P241= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- LRRC30 | c.192C>T p.P64= | Silent (SNP) | VAF 31/392 reads (8%) | catalogued as rs771985235, COSV101274385, COSV67301906; called by muse, mutect2
- LRRK2 | c.2679G>A p.L893= | Silent (SNP) | VAF 38/476 reads (8%) | called by muse, mutect2
- LRRTM3 | c.567A>T p.G189= | Silent (SNP) | VAF 97/251 reads (39%) | called by muse, mutect2, varscan2
- MAP1LC3C | c.378C>A p.G126= | Silent (SNP) | VAF 87/190 reads (46%) | called by muse, mutect2, varscan2
- MAS1 | c.645G>A p.R215= | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as rs765050520, COSV53121589; called by muse, mutect2, varscan2
- MAST1 | c.4362C>A p.G1454= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MMP16 | c.69G>A p.L23= | Silent (SNP) | VAF 128/383 reads (33%) | called by muse, mutect2, varscan2
- MYO15A | c.8154G>A p.L2718= | Silent (SNP) | VAF 17/253 reads (7%) | called by muse, mutect2
- NBAS | c.5694A>T p.A1898= | Silent (SNP) | VAF 112/402 reads (28%) | called by muse, mutect2, varscan2
- NEB | c.13705C>A p.R4569= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as CM1213409, COSV50859766; called by muse, mutect2, varscan2
- NEIL3 | c.339T>C p.N113= | Silent (SNP) | VAF 54/107 reads (50%) | called by muse, mutect2, varscan2
- NELL1 | c.2277C>T p.I759= | Silent (SNP) | VAF 87/375 reads (23%) | called by muse, mutect2, varscan2
- NWD2 | c.12C>A p.A4= | Silent (SNP) | VAF 45/158 reads (28%) | called by muse, mutect2, varscan2
- OGDHL | c.1686T>C p.D562= | Silent (SNP) | VAF 73/235 reads (31%) | catalogued as rs1471819751; called by muse, mutect2, varscan2
- OR14K1 | c.891C>T p.S297= | Silent (SNP) | VAF 184/374 reads (49%) | catalogued as rs753325788, COSV51721218; called by muse, mutect2, varscan2
- OR1C1 | c.432A>T p.L144= | Silent (SNP) | VAF 84/291 reads (29%) | called by muse, mutect2, varscan2
- OR5H2 | c.804A>T p.A268= | Silent (SNP) | VAF 123/183 reads (67%) | called by muse, mutect2, varscan2
- OTOF | c.2286C>T p.G762= (on ENST00000272371 / NM_194248.3; = p.G15= on NM_004802.4) | Silent (SNP) | VAF 18/318 reads (6%) | catalogued as rs776939970; called by muse, mutect2
- PGRMC1 | c.564T>C p.D188= | Silent (SNP) | VAF 236/334 reads (71%) | called by muse, mutect2, varscan2
- PIGX | c.489G>T p.S163= | Silent (SNP) | VAF 85/566 reads (15%) | catalogued as COSV99582730; called by muse, mutect2, varscan2
- PON1 | c.42G>C p.L14= | Silent (SNP) | VAF 30/569 reads (5%) | called by muse, mutect2
- PRR16 | c.303A>T p.A101= (on ENST00000407149 / NM_001300783.2; = p.A78= on NM_016644.2) | Silent (SNP) | VAF 106/191 reads (55%) | called by muse, mutect2, varscan2
- PTPN13 | c.615A>C p.R205= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- PTPRB | c.1522C>T p.L508= | Silent (SNP) | VAF 87/526 reads (17%) | called by muse, mutect2, varscan2
- PTPRK | c.3138G>C p.T1046= (on ENST00000368215 / NM_001291984.2; = p.T1047= on NM_002844.4) | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV63909158; called by muse, mutect2, varscan2
- RFX3 | c.1602C>T p.V534= | Silent (SNP) | VAF 54/103 reads (52%) | called by muse, mutect2, varscan2
- RGL1 | c.87G>T p.L29= | Silent (SNP) | VAF 175/469 reads (37%) | catalogued as COSV58983621; called by muse, mutect2, varscan2
- RPS6KA2 | c.2130G>T p.R710= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.156T>A p.T52= | Silent (SNP) | VAF 126/417 reads (30%) | called by muse, mutect2, varscan2
- SLC23A3 | c.1134C>T p.S378= | Silent (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- SNRPN | c.315G>T p.G105= | Silent (SNP) | VAF 99/143 reads (69%) | catalogued as COSV57599111; called by muse, mutect2, varscan2
- SYNE1 | c.9120T>G p.V3040= (on ENST00000367255 / NM_182961.4; = p.V3047= on NM_033071.3) | Silent (SNP) | VAF 11/344 reads (3%) | called by muse, mutect2
- TANC2 | c.4581A>G p.E1527= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as rs754566705; called by muse, mutect2, varscan2
- TBCE | c.1132C>T p.L378= (on ENST00000366601; = p.L441= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 178/669 reads (27%) | called by muse, mutect2, varscan2
- TDRD12 | c.2436G>C p.A812= | Silent (SNP) | VAF 131/242 reads (54%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.1812C>G p.L604= | Silent (SNP) | VAF 185/506 reads (37%) | catalogued as rs750630388; called by muse, mutect2, varscan2
- TRBV3-1 | c.291C>A p.I97= | Silent (SNP) | VAF 32/228 reads (14%) | called by muse, varscan2
- TRMT1 | c.216C>A p.V72= | Silent (SNP) | VAF 183/278 reads (66%) | called by muse, mutect2, varscan2
- TTN | c.13239G>T p.R4413= (on ENST00000591111; = p.R4367= on NM_003319.4) | Silent (SNP) | VAF 34/504 reads (7%) | catalogued as COSV60058786; called by muse, mutect2
- UBL7 | c.816G>T p.L272= | Silent (SNP) | VAF 42/108 reads (39%) | called by muse, mutect2
- UBR5 | c.4212A>G p.T1404= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs73698725; called by muse, mutect2, varscan2
- USH2A | c.12621C>T p.A4207= | Silent (SNP) | VAF 62/392 reads (16%) | catalogued as rs369544099, COSV56325711; called by muse, mutect2
- VWDE | c.3033A>T p.P1011= | Silent (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1551C>T p.P517= | Silent (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- ZNF292 | c.5586G>T p.L1862= | Silent (SNP) | VAF 79/236 reads (33%) | called by muse, mutect2, varscan2
- ZNF764 | c.1150C>T p.L384= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- AC005670.2 | chr17:47049756 C>A | 3'Flank (SNP) | VAF 230/738 reads (31%) | called by muse, mutect2, varscan2
- AC025575.2 | n.150C>T | RNA (SNP) | VAF 73/216 reads (34%) | catalogued as rs1164680664; called by muse, mutect2, varscan2
- AC107023.1 | n.25+7665G>T | Intron (SNP) | VAF 24/494 reads (5%) | catalogued as rs1337276049; called by muse, mutect2
- AC244258.1 | n.932G>T | RNA (SNP) | VAF 153/523 reads (29%) | catalogued as rs372367773; called by muse, mutect2, varscan2
- ADH5P5 | chr5:23977888 C>A | 5'Flank (SNP) | VAF 62/192 reads (32%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.7C>G | RNA (SNP) | VAF 17/263 reads (6%) | called by muse, mutect2
- ANTXR2 | c.*17C>A | 3'UTR (SNP) | VAF 58/358 reads (16%) | catalogued as rs1220312165; called by muse, varscan2
- AP003062.1 | n.70C>A | RNA (SNP) | VAF 92/506 reads (18%) | called by muse, varscan2
- AP005119.2 | chr18:1359365 C>A | 3'Flank (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4781C>A | Intron (SNP) | VAF 77/253 reads (30%) | catalogued as COSV64208201; called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38997A>T | Intron (SNP) | VAF 120/356 reads (34%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1187dup | RNA (INS) | VAF 54/195 reads (28%) | called by mutect2, pindel, varscan2
- C19orf12 | chr19:29702349 G>A | 3'Flank (SNP) | VAF 108/445 reads (24%) | catalogued as rs1369277615; called by muse, mutect2, varscan2
- CBWD3 | c.707+64G>C | Intron (SNP) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- CCDC140 | n.633G>T | RNA (SNP) | VAF 48/79 reads (61%) | called by muse, mutect2, varscan2
- CXCL12 | c.*39C>A | 3'UTR (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.2029C>A | RNA (SNP) | VAF 14/158 reads (9%) | catalogued as COSV59727233; called by muse, mutect2
- DNM1P46 | n.487C>T | RNA (SNP) | VAF 97/194 reads (50%) | catalogued as rs759208290; called by muse, mutect2, varscan2
- DPF2 | c.637+573G>A | Intron (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- DPY19L2P1 | n.3413G>A | RNA (SNP) | VAF 112/386 reads (29%) | called by muse, mutect2, varscan2
- FAM205BP | n.1875C>A | RNA (SNP) | VAF 32/824 reads (4%) | called by muse, mutect2
- FEZ1 | c.-288C>T | 5'UTR (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- FMR1 | c.*953A>T | 3'UTR (SNP) | VAF 18/193 reads (9%) | catalogued as rs1557183099; called by muse, mutect2
- FTCDNL1 | c.211+1545A>T | Intron (SNP) | VAF 34/58 reads (59%) | called by muse, varscan2
- IGLV8OR8-1 | n.89C>T | RNA (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+462T>C | Intron (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- MIR892A | n.21G>T | RNA (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- MIR892A | n.20G>T | RNA (SNP) | VAF 17/22 reads (77%) | called by muse, mutect2, varscan2
- MYO1F | c.636+27del | Intron (DEL) | VAF 94/233 reads (40%) | called by pindel, varscan2
- NECAB1 | c.*3460G>C | 3'UTR (SNP) | VAF 41/339 reads (12%) | called by muse, mutect2, varscan2
- NFASC | c.91+2325G>A | Intron (SNP) | VAF 81/215 reads (38%) | catalogued as rs953415548; called by muse, mutect2, varscan2
- PIN1 | chr19:9835316 del GCGGAGCAGGCGCT | 5'UTR (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel
- RPL4 | c.-7C>G | 5'UTR (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*1215G>A | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- SLC22A25 | c.1071-1696C>A | Intron (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-39 | n.73G>T | RNA (SNP) | VAF 119/202 reads (59%) | catalogued as rs756594303; called by muse, mutect2, varscan2
- SNORD116-8 | n.69C>T | RNA (SNP) | VAF 137/251 reads (55%) | called by muse, mutect2, varscan2
- TGM2 | c.1615+32A>C | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- TRIM36 | c.63+2212C>A | Intron (SNP) | VAF 114/204 reads (56%) | called by muse, varscan2
- WRN | c.-45A>G | 5'UTR (SNP) | VAF 52/151 reads (34%) | called by muse, mutect2, varscan2
- ZNF98 | c.-35C>T | 5'UTR (SNP) | VAF 52/138 reads (38%) | catalogued as COSV63340563; called by muse, mutect2, varscan2
